CCDI case PBCEUG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bd0174c1-8f5d-4a86-9389-8eead4a49696

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 6.5 years (2,380 days).

Biospecimens (3 samples)
- Sample 0DQ7WH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ810: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
